Gene-level copy-number profile of tumor specimen C3N-02256-01 from CPTAC case C3N-02256, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 65.1 years (23,761 days).
Specimen C3N-02256-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b5911a14-a538-4457-b77b-76a255275f7f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-02256-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,708 have no estimate.
https://portal.gdc.cancer.gov/files/48dd575e-986c-46d0-a61c-f3926949fe61

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 511; copy number 1: 2,296; copy number 2: 52,702; copy number 3: 474; copy number 4: 2,812; copy number 5: 69; copy number 6: 2; copy number 40: 13; copy number 46: 4; copy number 48: 8; copy number 56: 18; copy number 58: 2; copy number 59: 4.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 120 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:52,712,394–52,866,821, 1 gene, copy number 56 (within-gene range 2–56): LINC01618.
- chr4:52,722,618–54,446,723, 29 genes, copy number 6–59: ERVMER34-1, AC104066.1, Y_RNA, RASL11B, SCFD2, AC023154.1, RNU6-310P, FIP1L1, AC058822.1, LNX1, LNX1-AS1, AC095040.1, LNX1-AS2, AC124017.1, AC105384.1, AC105384.2, RPL21P44, AC110792.3, CHIC2, AC110792.2, AC110792.4, AC110792.1, MORF4L2P1, GSX2, RPL22P13, PDGFRA, LINC02283, AC098587.1, AC098868.1.
- chr7:12,211,270–13,751,920, 17 genes, copy number 5: TMEM106B, VWDE, AC013470.3, AC013470.2, SSBL5P, TAS2R2P, AC013470.1, AC005281.1, SCIN, AC011891.2, AC011891.3, ARL4A, AC011891.1, AC011287.1, RN7SKP228, RBMX2P4, AC011287.2.
- chr7:65,873,074–67,362,950, 52 genes, copy number 5: VKORC1L1, GUSB, AC073261.1, AC068533.2, AC068533.1, ASL, AC068533.4, CRCP, AC068533.3, TPST1, RNU6-313P, LINC00174, GTF2IP9, SKP1P1, AC008267.2, AC008267.4, AC008267.7, AC008267.5, AC008267.6, GS1-124K5.4, AC008267.1, AC008267.3, AC006001.3, AC006001.4, SAPCD2P3, AC006001.1, RPL35P5, KCTD7, AC027644.4, AC006001.2, RABGEF1, AC027644.3, AC027644.2, GTF2IRD1P1, AC027644.1, GTF2IP23, RNU6-1254P, LINC02604, AC073335.1, Metazoa_SRP, TMEM248, RN7SL43P, SBDS, TYW1, AC073089.1, MIR4650-1, SPDYE21, PMS2P4, Y_RNA, STAG3L4, AC006480.1, AC006480.2.
- chr12:53,251,251–53,254,406, 1 gene, copy number 48: MFSD5.
- chr12:57,723,761–57,808,071, 13 genes, copy number 40: AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AC025165.5, RNU6-1083P.
- chr12:57,869,834–57,984,761, 7 genes, copy number 48: AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2.

Autosomal genes at a single copy (total copy number 1): 2,296. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
